Surgical pathology report (de-identified scan), TCGA case TCGA-YU-AA4L, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-AA4L-01A (Primary Tumor).

ICD-O-3
Carcinoma, embryonal NOS 9070/3
Site^R Testis NOS C62.9
9/23/14

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

1 - "Right Testicle":

Embryonal carcinoma characterized as follows:

- . Measure of neoplasia in its major axis: 1.8 cm.
- . Neoplasia limited to the testis.
- . Tunica albuginea preserved.
- . Extensive areas of necrosis.
- . Neural infiltration not observed
- . Lymphatic vascular invasion not detected.
- . Sanguineous vascular invasion not detected.
- . Spermatic cord and epididymis free of neoplastic involvement.
- . Surgical margins free of neoplastic involvement.

PwTSS - 100% embryonal

Source: NCI Genomic Data Commons file a95b828f-3910-4f87-a655-fd44cc4b32b4 (TCGA-YU-AA4L.CB6BB5CD-9051-46F9-A893-EE50C93504BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).